Somatic mutation profile of tumor specimen 0DKIIH from CCDI case PBBYJP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.9 years (3,625 days).
Specimen 0DKIIH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7149ef7e-5bd1-4032-942e-d363fed96ccc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DKIHV (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6d7a75e6-663f-42e2-94ea-8995aec319b9

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 98/677 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by mutect2, varscan2
- ACAD10 | c.1778C>T p.A593V | Missense Mutation (SNP) | VAF 289/805 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as rs1183799240, COSV58158109; called by muse, mutect2, varscan2
- PRCP | c.1013C>T p.S338L | Missense Mutation (SNP) | VAF 24/833 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs1044013383, COSV57287489; called by muse, mutect2
- TFAP2D | c.724G>T p.E242* | Nonsense Mutation (SNP) | VAF 26/867 reads (3%) | catalogued as rs1320341834; called by muse, mutect2
